Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4846, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4846-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: KIDNEY, RIGHT, LAPAROSCOPIC RADICAL NEPHRECTOMY—

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, FUHRMAN NUCLEAR GRADE 2 OF 4, 7.6 CM IN MAXIMUM DIMENSION.
- B. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE, BUT TUMOR INVADES INTO SINUS FAT (slide 1C).
- C. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- F. THE ADRENAL GLAND IS NOT SUBMITTED.
- G. TNM STAGE: pT3a NX MX.
- H. TNM HISTOLOGIC GRADE = G2.

PART 2: LIVER, "SEGMENT 6," PARTIAL EXCISION— HEMANGIOMA.

Source: NCI Genomic Data Commons file b3bc6c69-53ca-4c41-85c2-b4c06712f731 (TCGA-B0-4846.763B36AC-446C-4492-AEE1-FF5BB9382E5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).